Somatic mutation profile of tumor specimen TCGA-DU-5855-01A (aliquot TCGA-DU-5855-01A-11D-1705-08) from TCGA case TCGA-DU-5855, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 49.9 years (18,234 days).
Specimen TCGA-DU-5855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f22e2312-be64-4c31-960e-2c14fd0f309e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5855-10A (Blood Derived Normal), aliquot TCGA-DU-5855-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/612e66fe-76a6-4da4-aec1-feb0ac9269d6

The open-access MAF lists 56 somatic variants for this specimen: 35 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 20, Nonsense Mutation 2, 3'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 44/151 reads (29%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 22/25 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.1425C>T p.L475= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as rs1294748012, COSV100074503; called by muse, varscan2
- ARHGEF6 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 13/241 reads (5%) | catalogued as COSV51692881; called by muse, mutect2
- ASB9 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV66852117; called by muse, mutect2, varscan2
- CCDC88C | c.4417G>A p.A1473T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs747515656, COSV58662500, COSV58662843; called by muse, mutect2
- CFHR5 | c.1489T>C p.W497R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56825637; called by muse, mutect2, varscan2
- CTC1 | c.3269A>G p.N1090S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs368562418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF2AK4 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs1205629925, COSV55472083; called by muse, mutect2, varscan2
- FGD6 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59695533; called by muse, mutect2
- FLNB | c.1967A>G p.E656G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1333827366, COSV55888837; called by muse, mutect2, varscan2
- FOSB | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs747823029, COSV100798682, COSV62279056; called by muse, mutect2, varscan2
- GFM2 | c.1276T>G p.S426A | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV57192493; called by muse, mutect2, varscan2
- HDAC5 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs138137922, COSV56822512; called by muse, mutect2, varscan2
- IFIH1 | c.1913T>G p.F638C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.312); catalogued as COSV55128782; called by muse, mutect2, varscan2
- KCNMB4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1289045846, COSV50690679, COSV50690910; called by muse, mutect2, varscan2
- KRT73 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1276797311, COSV59840933; called by muse, mutect2, varscan2
- LMTK2 | c.3365G>A p.G1122E | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV52000687; called by muse, mutect2, varscan2
- MAGEC3 | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.619); catalogued as COSV71610098; called by muse, mutect2, varscan2
- MAP3K19 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.289); catalogued as COSV59640955; called by muse, mutect2, varscan2
- MDM4 | c.1012A>C p.T338P | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV65796382; called by muse, mutect2, varscan2
- MIA2 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs752272838, COSV54497339; called by muse, mutect2, varscan2
- PCDHAC1 | c.1694T>C p.V565A | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV53862199; called by muse, mutect2
- PCLO | c.10120T>C p.Y3374H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61653733; called by muse, mutect2
- PLCG1 | c.2261A>G p.Y754C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54821640; called by muse, mutect2, varscan2
- PSMD3 | c.987C>G p.H329Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV52858996; called by muse, varscan2
- PTPRF | c.4013C>T p.A1338V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs371752134; called by muse, mutect2, varscan2
- SHH | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM012473, CM095867, COSV51919652; called by muse, mutect2, varscan2
- SORL1 | c.2188A>G p.K730E | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV52759101; called by muse, mutect2, varscan2
- STK10 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as rs563239491, COSV51577046; called by muse, mutect2, varscan2
- SVEP1 | c.10459G>T p.A3487S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV52842125; called by muse, mutect2, varscan2
- TMEM9 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66244043; called by muse, mutect2
- WNK1 | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV60041007, COSV60049486; called by muse, mutect2
- ARID2 | c.4047_4056del p.K1350* | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- ANK2 | c.10572C>T p.T3524= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs755318841, COSV52177898; called by muse, mutect2, varscan2
- ATRX | c.7206C>A p.I2402= | Silent (SNP) | VAF 9/212 reads (4%) | catalogued as COSV64880756; called by muse, mutect2
- CCR7 | c.372C>T p.F124= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs371166143, COSV55850095; called by muse, mutect2, varscan2
- CLDN4 | c.162C>T p.C54= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1554634058, COSV52896694; called by muse, mutect2
- COG5 | c.75C>G p.V25= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV51758933; called by muse, mutect2, varscan2
- EEF2 | c.2362C>T p.L788= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs777077931, COSV58579557; called by muse, mutect2
- EPPK1 | c.5187C>T p.F1729= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs781920013, COSV73260850; called by muse, mutect2, varscan2
- HECTD4 | c.11088C>G p.V3696= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs764546282, COSV66396685; called by muse, mutect2, varscan2
- HHIPL2 | c.372G>A p.T124= | Silent (SNP) | VAF 38/198 reads (19%) | catalogued as COSV58566633; called by muse, mutect2, varscan2
- IGF2BP2 | c.1060C>T p.L354= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as COSV60489427; called by muse, mutect2, varscan2
- ITIH2 | c.2073G>A p.T691= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1387689911, COSV64432462; called by muse, mutect2, varscan2
- KLHL14 | c.711G>A p.A237= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV63833219; called by muse, mutect2, varscan2
- MAGEB10 | c.702C>T p.D234= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs758228313, COSV63312264; called by muse, mutect2, varscan2
- NGDN | c.93A>G p.Q31= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV68142739; called by muse, mutect2
- PLXNA4 | c.4437C>T p.G1479= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs762377518, COSV58116557; called by muse, mutect2, varscan2
- PRND | c.435C>T p.C145= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs779451602, COSV59896285, COSV59896493; called by muse, mutect2, varscan2
- RAG1 | c.1821C>T p.D607= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs183806098, COSV55026947; called by muse, mutect2, varscan2
- SCMH1 | c.483G>A p.S161= (on ENST00000326197 / NM_001031694.2; = p.S114= on NM_012236.4) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs749827579, COSV58238060; called by muse, mutect2, varscan2
- SEC24D | c.2875C>T p.L959= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV54882960; called by muse, mutect2, varscan2
- SOHLH2 | c.204T>C p.V68= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV58522823; called by muse, mutect2, varscan2
- LEKR1 | c.*1514A>G | 3'UTR (SNP) | VAF 34/91 reads (37%) | catalogued as COSV62963670; called by muse, varscan2
